Somatic mutation profile of tumor specimen TCGA-DB-A75L-01A (aliquot TCGA-DB-A75L-01A-11D-A32B-08) from TCGA case TCGA-DB-A75L, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 36.5 years (13,338 days).
Specimen TCGA-DB-A75L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 740c2fd7-80d0-48a9-a7e8-303335578d4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A75L-10A (Blood Derived Normal), aliquot TCGA-DB-A75L-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b30146d-d9db-4a5f-8b9a-4f3b26208113

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 23, Silent 6, Frame Shift Ins 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- DMD | c.6857A>G p.E2286G | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100627258; called by muse, mutect2, varscan2
- DYNC2LI1 | c.804A>T p.G268= | Splice Region (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99571208; called by muse, mutect2, varscan2
- EPHA5 | c.1945A>G p.T649A | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.48); catalogued as COSV99898922; called by muse, mutect2, varscan2
- GDE1 | c.674C>G p.T225S | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV100783190; called by muse, mutect2, varscan2
- GPC4 | c.1598G>C p.R533P | Missense Mutation (SNP) | VAF 106/233 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100895478, COSV63697547; called by muse, mutect2, varscan2
- GRIK2 | c.530A>T p.D177V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100026157; called by muse, mutect2, varscan2
- ILVBL | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as rs772794806, COSV99654860; called by muse, mutect2
- KCNJ5 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100610673; called by muse, mutect2, varscan2
- LIG3 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52005519; called by muse, mutect2, varscan2
- MMP10 | c.83A>G p.D28G | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV99666554; called by muse, mutect2, varscan2
- OLFM2 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs780979962, COSV53429225; called by mutect2, varscan2
- PCYOX1L | c.1172C>G p.A391G | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.647); catalogued as COSV99199195; called by muse, mutect2, varscan2
- PGK1 | c.373C>A p.H125N | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100965332; called by muse, mutect2, varscan2
- PPP2R1B | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1400517304, COSV100232167; called by muse, mutect2, varscan2
- PTPRM | c.2302A>G p.K768E | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100157318; called by muse, mutect2
- RBMS1 | c.1046T>C p.L349P | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100816868; called by muse, mutect2, varscan2
- SARM1 | c.1582G>A p.G528S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.192); catalogued as COSV50229321, COSV99134984; called by muse, mutect2, varscan2
- SIGLEC5 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV55778722; called by muse, mutect2, varscan2
- SYNE2 | c.11429A>G p.N3810S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs772602777, COSV100647686; called by muse, mutect2, varscan2
- TLL1 | c.926T>C p.F309S | Missense Mutation (SNP) | VAF 48/297 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV99287369; called by muse, mutect2, varscan2
- TMTC2 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV100337529; called by muse, mutect2, varscan2
- TNXB | c.6071G>A p.R2024H (on ENST00000647633; = p.R1777H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); catalogued as rs767799073, COSV64482909; called by muse, mutect2, varscan2
- TSPYL6 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as rs773922991, COSV100336626; called by muse, mutect2, varscan2
- LAMA3 | c.7505_7508dup p.Y2503* (on ENST00000313654 / NM_198129.4; = p.Y894* on NM_000227.6) | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | called by mutect2, varscan2
- NOTCH1 | c.1837dup p.R613Pfs*32 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by mutect2, pindel, varscan2
- SH3D19 | c.303_325del p.E102Wfs*7 | Frame Shift Del (DEL) | VAF 32/132 reads (24%) | called by mutect2, varscan2
- C2orf16 | c.318G>A p.E106= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV101284391; called by muse, mutect2, varscan2
- DHX36 | c.516A>G p.Q172= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100273601; called by muse, mutect2, varscan2
- NLGN3 | c.939A>G p.Q313= (on ENST00000358741 / NM_181303.2; = p.Q293= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100704769; called by muse, mutect2, varscan2
- OLFM2 | c.315G>T p.A105= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV99321801; called by muse, mutect2, varscan2
- OR4M1 | c.72A>G p.Q24= | Silent (SNP) | VAF 29/245 reads (12%) | catalogued as rs1311915749, COSV100271013; called by muse, mutect2, varscan2
- TMEM185A | c.280T>C p.L94= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as COSV100383056; called by muse, mutect2, varscan2
